Somatic mutation profile of tumor specimen 0DLA1V from CCDI case PBBZAG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.1 years (3,325 days).
Specimen 0DLA1V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aac95b3b-14a2-4ec8-980f-3094eb9d5eb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLA10 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/689a56ed-8846-42ec-9d38-288b9a56078e

The open-access MAF lists 42 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 9, 3'UTR 4, Intron 2, Nonsense Mutation 2, Frame Shift Del 2, In Frame Del 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 123/486 reads (25%) | catalogued as rs1554898053, CM981668, COSV64289438; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CFAP300 | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 83/750 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs766791307; called by muse, mutect2, varscan2
- CORIN | c.529T>G p.Y177D | Missense Mutation (SNP) | VAF 167/2096 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV104385081; called by muse, mutect2
- CRHR2 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 82/988 reads (8%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs548065920, COSV100793251; called by muse, mutect2
- DKK2 | c.350G>A p.C117Y | Missense Mutation (SNP) | VAF 122/1184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53393484; called by muse, mutect2, varscan2
- DMD | c.7404G>T p.E2468D | Missense Mutation (SNP) | VAF 647/814 reads (79%) | SIFT tolerated (0.18); PolyPhen benign (0.283); catalogued as COSV100628940; called by muse, mutect2, varscan2
- DUOX2 | c.3631C>T p.R1211C | Missense Mutation (SNP) | VAF 170/1338 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374410986, CM159749; called by muse, mutect2, varscan2
- INHBC | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 193/506 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs768130925, COSV59006206; called by muse, mutect2, varscan2
- MYH13 | c.-12C>A | Splice Region (SNP) | VAF 43/381 reads (11%) | catalogued as rs776111236; called by muse, mutect2, varscan2
- SEC16A | c.1591G>A p.G531R | Missense Mutation (SNP) | VAF 65/650 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1402630519, COSV51529007; called by muse, mutect2
- SNX9 | c.1570G>C p.V524L | Missense Mutation (SNP) | VAF 463/1255 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs746580173; called by muse, mutect2, varscan2
- TNFSF15 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 77/1080 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs889534030, COSV65011132; called by muse, mutect2
- TTN | c.58388G>C p.R19463T (on ENST00000591111; = p.R12039T on NM_003319.4) | Missense Mutation (SNP) | VAF 483/1156 reads (42%) | PolyPhen probably damaging (0.996); catalogued as COSV59894093; called by muse, mutect2, varscan2
- CEACAM16 | c.817A>G p.N273D | Missense Mutation (SNP) | VAF 270/580 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- COMMD1 | c.346A>G p.N116D | Missense Mutation (SNP) | VAF 76/860 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- INSYN2B | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 140/1683 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- INTS6 | c.2110G>T p.E704* | Nonsense Mutation (SNP) | VAF 94/673 reads (14%) | called by muse, mutect2, varscan2
- LINGO2 | c.1520G>C p.R507P | Missense Mutation (SNP) | VAF 123/1474 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.271); called by muse, mutect2
- MTMR7 | c.1846G>T p.D616Y | Missense Mutation (SNP) | VAF 135/1085 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- MUCL3 | c.496A>C p.I166L | Missense Mutation (SNP) | VAF 154/1450 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCDH12 | c.2792T>C p.I931T | Missense Mutation (SNP) | VAF 34/690 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2
- PI4KA | c.5011del p.E1671Sfs*21 | Frame Shift Del (DEL) | VAF 255/718 reads (36%) | called by mutect2, pindel, varscan2
- UXS1 | c.201A>C p.R67S | Missense Mutation (SNP) | VAF 92/1298 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- WDR64 | c.1004C>A p.A335E | Missense Mutation (SNP) | VAF 36/1324 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- ZFP36L2 | c.706_715delinsA p.F236_R239delinsS | In Frame Del (DEL) | VAF 133/383 reads (35%) | called by pindel, varscan2*
- ZNF106 | c.1221del p.E408Kfs*22 | Frame Shift Del (DEL) | VAF 114/1191 reads (10%) | called by mutect2, pindel
- ARAP3 | c.4095T>A p.S1365= | Silent (SNP) | VAF 383/780 reads (49%) | called by muse, mutect2, varscan2
- C16orf96 | c.1935C>T p.Y645= | Silent (SNP) | VAF 160/385 reads (42%) | catalogued as rs769203413; called by muse, mutect2, varscan2
- CELSR1 | c.3513G>A p.P1171= | Silent (SNP) | VAF 61/533 reads (11%) | catalogued as rs371346729; called by muse, mutect2, varscan2
- GPR37L1 | c.1011C>A p.G337= | Silent (SNP) | VAF 34/530 reads (6%) | called by muse, mutect2
- LEP | c.174C>T p.T58= | Silent (SNP) | VAF 111/1523 reads (7%) | catalogued as rs199647957; called by muse, mutect2
- OR6K6 | c.180T>C p.L60= (on ENST00000368144; = p.L36= on NM_001005184.1) | Silent (SNP) | VAF 163/1193 reads (14%) | called by muse, mutect2, varscan2
- RHBDF2 | c.1338C>T p.Y446= | Silent (SNP) | VAF 58/926 reads (6%) | catalogued as rs143587407; called by muse, mutect2
- WDR72 | c.1404C>G p.L468= | Silent (SNP) | VAF 120/1478 reads (8%) | called by muse, mutect2
- ZNF835 | c.1008C>T p.C336= | Silent (SNP) | VAF 52/466 reads (11%) | called by muse, mutect2, varscan2
- CPED1 | c.*34G>T | 3'UTR (SNP) | VAF 70/692 reads (10%) | called by muse, mutect2
- CPED1 | c.*35A>G | 3'UTR (SNP) | VAF 66/672 reads (10%) | catalogued as rs746080658; called by muse, mutect2
- DNAJB11 | c.456+66A>C | Intron (SNP) | VAF 236/512 reads (46%) | called by muse, mutect2, varscan2
- GJB3 | c.*56G>A | 3'UTR (SNP) | VAF 26/141 reads (18%) | called by muse, mutect2, varscan2
- PGAP3 | c.557+72del | Intron (DEL) | VAF 25/257 reads (10%) | called by mutect2, pindel, varscan2
- SLC44A1 | c.*90T>A | 3'UTR (SNP) | VAF 45/424 reads (11%) | called by muse, mutect2
- SPATA31C1 | n.3069_3070del | RNA (DEL) | VAF 64/484 reads (13%) | called by mutect2, varscan2
